Somatic mutation profile of tumor specimen 0DRO3U from CCDI case PBCEUU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningiomatosis, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.0 years (4,017 days).
Specimen 0DRO3U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33fd01d7-32ba-4980-a7c6-71a818412a3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRO3H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7e5a34b-3e34-4d85-9f6d-9d1eae4bc744

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.1146C>T p.P382= (on ENST00000326724 / NM_001080395.3; = p.P279= on NM_004920.2) | Silent (SNP) | VAF 46/232 reads (20%) | catalogued as rs551487787; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
